Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3655, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3655-01A (Primary Tumor).

Diagnosis/ diagnoses:

Resection material from (sigmoid) colon shows a colon carcinoma characterized histologically as a moderately differentiated colorectal adenocarcinoma, extending to within 6.5 cm of a resection margin at most and measuring 4 cm in diameter at the widest point. Infiltrative tumor spread within all parietal layers of the colon to the bordering mesocolic fatty tissue. In addition, the mucous membrane of the colon has a small tubulovillous adenoma with moderate epithelial dysplasia (synonym: low-grade epithelial neoplasia). The oral and aboral resection margins are tumor-free.

Twenty-two mesocolic local lymph nodes are tumor-free with uncharacteristic reactive lesions.

The tumor stage is pT3 pN0 (0/22) L0V0; G2

Source: NCI Genomic Data Commons file 6d92ab86-e039-47fa-9db6-2e7bfed12b76 (TCGA-AA-3655.595CECD4-765B-4EC9-8BE1-C971A6840904.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).